Gene-level copy-number profile of tumor specimen TCGA-EE-A29H-06A from TCGA case TCGA-EE-A29H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.3 years (22,397 days).
Specimen TCGA-EE-A29H-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.65173be6-944b-44cb-8c2a-20d959792594.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A29H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 849 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/883854d3-b42e-4c86-9c87-dee18a92ea21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 14,289; copy number 2: 42,437; copy number 3: 2,283; copy number 4: 8; copy number 5: 203; copy number 6: 130; copy number 7: 105; copy number 8: 74; copy number 10: 197.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A29H-06A-12D-A191-01): tumor purity 0.86, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,165,552, 48 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 709 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,362,613–50,504,244, 1 gene, copy number 6 (within-gene range 3–6): CACNA2D2.
- chr3:50,558,025–79,767,998, 409 genes, copy number 6–10 (within-gene range 2–10) (broad region; genes not listed).
- chr3:81,489,703–82,463,675, 7 genes, copy number 6 (within-gene range 2–6): GBE1, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23.
- chr7:136,685,559–137,182,107, 1 gene, copy number 5 (within-gene range 3–5): AC009264.1.
- chr7:136,868,669–142,106,747, 117 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:142,618,849–143,836,933, 89 genes, copy number 7 (broad region; genes not listed).
- chr7:144,451,941–150,343,346, 85 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,212. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
